Somatic mutation profile of tumor specimen TCGA-2G-AAFH-01A (aliquot TCGA-2G-AAFH-01A-12D-A42Y-10) from TCGA case TCGA-2G-AAFH, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.7 years (14,120 days).
Specimen TCGA-2G-AAFH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbd8b872-4112-45ec-9d00-59235d0b2fa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFH-10A (Blood Derived Normal), aliquot TCGA-2G-AAFH-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/423b5895-61c2-405c-aa4b-7d307c60abbc

The open-access MAF lists 24 somatic variants for this specimen: 19 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL18A1 | c.3200C>T p.A1067V (on ENST00000359759 / NM_130444.3; = p.A832V on NM_030582.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as rs1436717929, COSV100645167; called by muse, mutect2, varscan2
- COL22A1 | c.3857C>T p.A1286V | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs775008648; called by muse, mutect2, varscan2
- KRT73 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.748); catalogued as rs749189326; called by muse, mutect2, varscan2
- OTX2 | c.115C>T p.R39C (on ENST00000408990 / NM_172337.3; = p.R47C on NM_021728.4) | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257937; called by muse, mutect2, varscan2
- POPDC3 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs567589295; called by muse, mutect2, varscan2
- UBR4 | c.5773C>T p.Q1925* | Nonsense Mutation (SNP) | VAF 41/275 reads (15%) | catalogued as COSV64393226; called by muse, mutect2, varscan2
- ANO7 | c.2622C>G p.D874E (on ENST00000274979; = p.D820E on NM_001370694.2) | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- C17orf98 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CARD10 | c.624G>T p.M208I | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC152 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- DNAH6 | c.3356A>T p.D1119V | Missense Mutation (SNP) | VAF 71/504 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EPHB4 | c.763T>G p.C255G | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- GGA3 | c.997G>T p.D333Y (on ENST00000537686 / NM_138619.4; = p.D300Y on NM_014001.5) | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MORC3 | c.44G>T p.C15F | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by mutect2, varscan2
- PNPLA6 | c.2035C>T p.Q679* (on ENST00000414982 / NM_001166111.2; = p.Q631* on NM_006702.5) | Nonsense Mutation (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- RPL5 | c.217_218dup p.M73Ifs*2 | Frame Shift Ins (INS) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- TTN | c.97411T>A p.S32471T (on ENST00000591111; = p.S25047T on NM_003319.4) | Missense Mutation (SNP) | VAF 48/166 reads (29%) | PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF567 | c.1446_1447del p.C482Wfs*5 (on ENST00000536254 / NM_001322913.1; = p.C451Wfs*5 on NM_152603.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/117 reads (14%) | called by pindel, varscan2
- ZNF699 | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, varscan2
- H3C3 | c.60G>A p.Q20= | Silent (SNP) | VAF 28/148 reads (19%) | catalogued as rs1447072243; called by muse, mutect2, varscan2
- KCNS1 | c.958C>T p.L320= | Silent (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2, varscan2
- NF1 | c.510C>T p.D170= | Silent (SNP) | VAF 11/89 reads (12%) | called by muse, mutect2, varscan2
- ODF2 | c.2376C>T p.S792= (on ENST00000434106 / NM_153433.2; = p.S768= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 34/110 reads (31%) | called by muse, mutect2, varscan2
- UBB | c.258C>G p.G86= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV56219795; called by muse, mutect2
